HCMI case HCM-CSHL-0509-C24 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Other and unspecified parts of biliary tract. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/6ecd59ce-a391-4187-87a3-a69a71919585

Demographics
Sex at birth: male; Year of birth: 1947; Vital status: Dead; Days to death: 303 days; Cause of death: Cancer Related.

Diagnoses (2)
1. Neuroendocrine carcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8246/3; ICD-10 code: C24.1; Tissue or organ of origin: Ampulla of Vater; Classification of tumor: primary; Age at diagnosis: 71.8 years (26,219 days); AJCC staging edition: 8th; AJCC pathologic T: T2; AJCC pathologic N: N2; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIIB; Tumor grade: G3; Metastasis at diagnosis: Metastasis, NOS; Prior malignancy: no; Prior treatment: No; Residual disease: R0; Sites of involvement: Lymph Node, Regional; Tumor confined to organ of origin: No.
   Pathology details: Lymph nodes positive: 5; Lymph nodes tested: 32; Lymphatic invasion present: Yes; Perineural invasion present: No; Vascular invasion present: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: -13 days.
   Recorded as not given: neoadjuvant treatment (type not reported); adjuvant Pharmaceutical Therapy, NOS, for residual disease; adjuvant Radiation Therapy, NOS, for residual disease.
2. Neuroendocrine carcinoma, NOS: ICD-O-3 morphology code: 8246/6; ICD-10 code: C77.2; Tissue or organ of origin: Ampulla of Vater; Site of resection or biopsy: Lymph node, NOS; Classification of tumor: metastasis; Age at diagnosis: 71.8 years (26,219 days); Residual disease: R0; Tumor confined to organ of origin: No.
   Pathology details: Lymph nodes positive: 5; Lymph nodes tested: 32; Lymphatic invasion present: Yes; Perineural invasion present: No; Vascular invasion present: Yes.

Follow-up (2 entries)
- Days to follow up: 0 days; Progression or recurrence: Yes; Progression or recurrence type: Regional; Progression or recurrence anatomic site: Lymph node, NOS; Days to progression: 0 days.
- Follow-up contacts recording only the day: day 62, day 303.

Molecular and laboratory tests
- CD56 (IHC): Positive.
- CHGA (IHC): Negative.
- Ki67 (IHC): 60 percent.
- Ki67 (IHC): 600; Cell count: 1000.
- SYP (IHC): Equivocal.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 79 kg; Height: 179 cm; BMI: 25.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Family history
- Relative with cancer history: yes; Relationship type: First Degree Relative, NOS; Relationship primary diagnosis: Cancer.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample HCM-CSHL-0509-C24-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
  Slide HCM-CSHL-0509-C24-06A-01-S2-HE: Section location: Bottom; Percent tumor cells: 85; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 15; Percent lymphocyte infiltration: 4; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 3.
  Slide HCM-CSHL-0509-C24-06A-01-S1-HE: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 20; Percent lymphocyte infiltration: 6; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 5.
- Sample HCM-CSHL-0509-C24-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample HCM-CSHL-0509-C24-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 10.
